Somatic mutation profile of tumor specimen TCGA-BR-7704-01A (aliquot TCGA-BR-7704-01A-11D-2053-08) from TCGA case TCGA-BR-7704, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.3 years (25,300 days).
Specimen TCGA-BR-7704-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1bd6524-0074-4055-9550-fc2792955bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7704-10A (Blood Derived Normal), aliquot TCGA-BR-7704-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dbdd1e2-2080-4c22-9f91-70cfb3d899d4

The open-access MAF lists 395 somatic variants for this specimen: 299 protein-altering or splice-affecting, 85 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 85, Nonsense Mutation 20, Splice Site 10, Intron 8, Splice Region 4, Frame Shift Ins 3, Frame Shift Del 3, Nonstop Mutation 2, In Frame Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 105/284 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- PRX | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 54/98 reads (55%) | catalogued as rs756689732, CM1411882, COSV52532630; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519724, COSV64288957, COSV64298985; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99445935; called by muse, mutect2, varscan2
- ABCB5 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99327559; called by muse, mutect2, varscan2
- ABCC9 | c.3290C>T p.S1097L | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53983620; called by muse, mutect2, varscan2
- AC131160.1 | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as rs763167412, COSV57702328; called by muse, mutect2, varscan2
- AC139530.2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100230276, COSV61270728; called by muse, mutect2, varscan2
- ACBD3 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); catalogued as COSV100830901; called by muse, mutect2, varscan2
- ADAMTS13 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138742754, BM1115006; called by muse, mutect2, varscan2
- ADAMTS3 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV99710364, COSV99712378; called by muse, mutect2, varscan2
- ADCY7 | c.1868T>A p.V623E | Missense Mutation (SNP) | VAF 83/137 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV99575721; called by muse, mutect2, varscan2
- ADCY7 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs775962958, COSV54268855; called by muse, mutect2, varscan2
- ADGRV1 | c.3530A>C p.N1177T | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101315546; called by muse, mutect2, varscan2
- ADGRV1 | c.12851T>G p.V4284G | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101315547; called by muse, mutect2, varscan2
- ADTRP | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99995080; called by muse, mutect2, varscan2
- AGRN | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV101038623; called by muse, mutect2
- ALKBH3 | c.168C>G p.F56L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100236094; called by muse, mutect2, varscan2
- ANO3 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as rs1334945680, COSV56784342, COSV99885817; called by muse, mutect2, varscan2
- APC | c.3311C>A p.S1104* | Nonsense Mutation (SNP) | VAF 71/111 reads (64%) | catalogued as CM106638, COSV57335791, COSV57382922; called by muse, mutect2, varscan2
- APC | c.3451_3453del p.E1151del | In Frame Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs761327787; called by pindel, varscan2
- APOL5 | c.964A>T p.R322W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99968342; called by muse, mutect2, varscan2
- AR | c.2440T>C p.F814L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.927); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- ARHGAP18 | c.1562T>G p.L521R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100936028, COSV63763474; called by muse, mutect2, varscan2
- ARHGAP32 | c.2162A>G p.K721R (on ENST00000310343 / NM_001378025.1; = p.K372R on NM_014715.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as rs769300044, COSV100087059; called by muse, mutect2, varscan2
- ARID2 | c.5364-1G>C p.X1788_splice | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100535516, COSV100536272; called by muse, mutect2, varscan2
- ATP8B1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 68/122 reads (56%) | catalogued as rs775370485, COSV52177909; called by muse, mutect2, varscan2
- ATRNL1 | c.3473T>G p.I1158S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100369515; called by muse, mutect2, varscan2
- ATRX | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100970173; called by muse, mutect2, varscan2
- BFAR | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV99902034; called by muse, mutect2, varscan2
- BPIFB6 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as rs775084528, COSV100848490; called by muse, mutect2, varscan2
- BRD2 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100875575; called by muse, mutect2, varscan2
- CACNA1I | c.1003A>T p.K335* | Nonsense Mutation (SNP) | VAF 56/125 reads (45%) | catalogued as COSV100359385; called by muse, mutect2, varscan2
- CACNA1I | c.4260C>A p.F1420L | Missense Mutation (SNP) | VAF 97/379 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100359389; called by muse, mutect2, varscan2
- CADM2 | c.250T>A p.W84R (on ENST00000407528 / NM_001167674.2; = p.W86R on NM_153184.4) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.89); catalogued as COSV101053119; called by muse, mutect2, varscan2
- CDHR2 | c.3048C>A p.Y1016* | Nonsense Mutation (SNP) | VAF 49/192 reads (26%) | catalogued as COSV99991117; called by muse, mutect2, varscan2
- CEACAM7 | c.674G>C p.S225T | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99137144; called by muse, mutect2, varscan2
- CEP19 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); catalogued as COSV99582206; called by muse, mutect2, varscan2
- CEP44 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as COSV99639238; called by muse, mutect2, varscan2
- CFAP61 | c.1317A>C p.K439N | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99843536; called by muse, mutect2
- CLCA1 | c.2314A>T p.T772S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.831); catalogued as COSV99321962; called by muse, mutect2, varscan2
- CNTN5 | c.2382G>A p.W794* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99673619; called by muse, mutect2
- CNTN6 | c.672A>T p.E224D | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100610178; called by muse, mutect2, varscan2
- COL11A1 | c.2510T>G p.L837R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100614690, COSV62175663, COSV62200150; called by muse, mutect2, varscan2
- COL15A1 | c.1712G>C p.G571A | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100897461; called by muse, mutect2, varscan2
- COL1A2 | c.2800G>A p.G934S | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51958839, COSV99798762; called by muse, mutect2, varscan2
- COL6A3 | c.3026T>G p.I1009R | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99796418; called by muse, mutect2, varscan2
- COMMD9 | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99661207; called by muse, mutect2, varscan2
- CPZ | c.1526T>C p.V509A (on ENST00000360986 / NM_001014447.3; = p.V498A on NM_003652.3) | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100248797; called by muse, mutect2, varscan2
- CRYBB1 | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315857; called by muse, mutect2, varscan2
- CSMD2 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs901155048, COSV53897001; called by muse, mutect2, varscan2
- CTNNA3 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101046644; called by muse, mutect2, varscan2
- CXCR1 | c.930A>C p.Q310H | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99826247; called by muse, mutect2, varscan2
- CXCR3 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV101031553; called by muse, mutect2
- CXorf66 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100983833, COSV65169503; called by muse, mutect2, varscan2
- CYP24A1 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99398079; called by muse, mutect2, varscan2
- DCDC1 | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100662813; called by muse, mutect2, varscan2
- DCUN1D3 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 102/174 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100176739; called by muse, mutect2, varscan2
- DGKE | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV99400709; called by muse, mutect2, varscan2
- DKC1 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101053850; called by muse, mutect2, varscan2
- DKK3 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58867834, COSV58868276; called by muse, mutect2, varscan2
- DMBT1 | c.5273C>T p.A1758V (on ENST00000338354 / NM_001377530.1; = p.A1001V on NM_004406.3) | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV100352281; called by muse, mutect2, varscan2
- DNAH1 | c.12736C>T p.H4246Y | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1343604692, COSV99963493; called by muse, mutect2, varscan2
- DNAJC10 | c.1893C>A p.Y631* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99898929; called by muse, mutect2, varscan2
- DPF2 | c.1017C>T p.D339= | Splice Region (SNP) | VAF 33/65 reads (51%) | catalogued as rs752651232, COSV99361377; called by muse, mutect2, varscan2
- DRD3 | c.569T>A p.I190N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99879216; called by muse, mutect2, varscan2
- DYRK1A | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117534, COSV58294108; called by muse, mutect2, varscan2
- EBF3 | c.1489G>A p.A497T (on ENST00000355311 / NM_001375392.1; = p.A488T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs138447716, COSV100799028; called by muse, mutect2, varscan2
- EDN3 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217486733, COSV61107624; called by muse, mutect2, varscan2
- EIF5AL1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101592771; called by muse, mutect2, varscan2
- EMSY | c.1802C>A p.T601K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58262323; called by muse, mutect2, varscan2
- ENOX1 | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99815173; called by muse, mutect2, varscan2
- EOMES | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as rs201822269; called by muse, mutect2, varscan2
- EXOC7 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV100134900; called by muse, mutect2, varscan2
- EZHIP | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as rs781990168, COSV100539509; called by muse, mutect2
- EZHIP | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100539511; called by muse, mutect2, varscan2
- FAM135B | c.1073A>C p.K358T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1173976891, COSV99419754; called by muse, mutect2, varscan2
- FBXO17 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.951); catalogued as COSV99493972; called by muse, mutect2, varscan2
- FBXO48 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376405; called by muse, varscan2
- FBXO48 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100376406; called by muse, varscan2
- FERMT2 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV100448736, COSV100449208; called by muse, mutect2, varscan2
- FOXN2 | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100489014; called by muse, mutect2, varscan2
- FRMPD2 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100563555; called by muse, mutect2, varscan2
- FSTL5 | c.1015+1G>A p.X339_splice | Splice Site (SNP) | VAF 39/124 reads (31%) | catalogued as COSV100053175; called by muse, mutect2, varscan2
- GABRB3 | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100158416, COSV100158479; called by muse, mutect2, varscan2
- GDF9 | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99737134; called by muse, mutect2, varscan2
- GDI1 | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99340873; called by muse, mutect2, varscan2
- GLRB | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.578); catalogued as COSV100029508, COSV52422617; called by muse, mutect2, varscan2
- GNPAT | c.1274G>C p.W425S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV100791568; called by muse, mutect2, varscan2
- GPSM3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100900424, COSV66679823; called by muse, mutect2, varscan2
- GRIN3A | c.2325A>C p.E775D | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as COSV100701385; called by muse, mutect2, varscan2
- GTF3C1 | c.2306A>C p.N769T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100649017; called by muse, mutect2, varscan2
- HDAC2 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100892555; called by muse, mutect2, varscan2
- HDLBP | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs202096199; called by muse, mutect2, varscan2
- HIVEP1 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101044786; called by muse, mutect2, varscan2
- HSPG2 | c.6226G>A p.G2076R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949316109, COSV101020456; called by muse, mutect2
- HTR1E | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100540977; called by muse, mutect2, varscan2
- IGF2R | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100806979; called by muse, mutect2, varscan2
- IGSF1 | c.3521A>T p.K1174M | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100811778, COSV100811883, COSV63839442; called by muse, mutect2, varscan2
- IGSF1 | c.1010A>C p.Q337P | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100811884; called by muse, mutect2, varscan2
- IL7R | c.66T>A p.S22R | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100285961; called by muse, mutect2, varscan2
- IRF1 | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99810408; called by muse, mutect2, varscan2
- ITGA5 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99516386; called by muse, mutect2, varscan2
- KCNF1 | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV99705569; called by muse, mutect2, varscan2
- KCNJ13 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV52085708; called by muse, mutect2, varscan2
- KCNMA1 | c.3301G>T p.A1101S (on ENST00000286628 / NM_001161352.2; = p.A1043S on NM_002247.4) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV54282988, COSV99695377; called by muse, mutect2, varscan2
- KCNQ3 | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV101195749; called by muse, mutect2, varscan2
- KDM1B | c.1114G>A p.D372N (on ENST00000449850; = p.D240N on NM_153042.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs147829792; called by muse, mutect2, varscan2
- KIAA1217 | c.4964C>T p.T1655I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100286259; called by muse, mutect2, varscan2
- KIAA1755 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs563109793, COSV99641559; called by muse, mutect2, varscan2
- KIF27 | c.1664T>G p.L555R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52825178; called by muse, mutect2, varscan2
- KLC1 | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99871239; called by muse, mutect2, varscan2
- KLHL25 | c.1266C>A p.N422K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs138577845, COSV100563460; called by muse, mutect2, varscan2
- KLHL28 | c.517_518insG p.F173Cfs*3 | Frame Shift Ins (INS) | VAF 37/142 reads (26%) | catalogued as COSV100752994; called by mutect2, pindel, varscan2
- KLRC3 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV101122891; called by muse, mutect2
- KPNA5 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100706107, COSV100706307; called by muse, mutect2
- KRT2 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV100548312; called by muse, mutect2, varscan2
- KRTAP4-3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs373753201; called by muse, varscan2
- LAMA2 | c.6964G>A p.E2322K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV101370178, COSV101370442; called by muse, mutect2, varscan2
- LCE2C | c.271T>C p.C91R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV100909396; called by muse, mutect2, varscan2
- LHCGR | c.1148T>G p.V383G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99683256; called by muse, mutect2, varscan2
- LMTK2 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs201907719, COSV51993890; called by muse, mutect2, varscan2
- LMX1A | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV99671733; called by muse, mutect2, varscan2
- LPAR4 | c.214A>C p.S72R | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101425081, COSV70912272; called by muse, mutect2, varscan2
- LRIG2 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1409826065, COSV100743027; called by muse, mutect2, varscan2
- LRP2 | c.6554T>G p.L2185R | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99786796; called by muse, mutect2, varscan2
- LRRK2 | c.6968T>C p.I2323T | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs200690628, COSV100109401, COSV54161813; called by muse, mutect2, varscan2
- LY86 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100040894; called by muse, mutect2, varscan2
- MADD | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100211116; called by muse, mutect2, varscan2
- MAGEA3 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 195/496 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as COSV100939002, COSV100939087, COSV64756320; called by muse, mutect2, varscan2
- MAGEA8 | c.513A>C p.E171D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99674425, COSV99674717; called by muse, mutect2, varscan2
- MAGEC1 | c.2951C>A p.S984Y | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.486); catalogued as rs1410181892, COSV53570830, COSV99594989; called by muse, mutect2, varscan2
- MAPK9 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV100558160; called by muse, mutect2, varscan2
- MAPKAP1 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99784413; called by muse, mutect2, varscan2
- MDN1 | c.7882G>T p.E2628* | Nonsense Mutation (SNP) | VAF 47/185 reads (25%) | catalogued as COSV101020836; called by muse, varscan2
- MMAA | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99849662; called by muse, mutect2, varscan2
- MMP2 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV99527476; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1311T>G p.A437= | Splice Region (SNP) | VAF 28/128 reads (22%) | catalogued as rs760737514, COSV99732476; called by muse, varscan2
- MPL | c.852A>C p.A284= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100991367; called by muse, mutect2, varscan2
- MS4A14 | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100280097; called by muse, mutect2, varscan2
- MSR1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100026690; called by muse, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MUC16 | c.6296C>G p.S2099C | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV101198404; called by muse, mutect2, varscan2
- MYH4 | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1451700052, COSV55119246; called by muse, mutect2, varscan2
- MYOM3 | c.2312A>T p.E771V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100292542; called by muse, mutect2, varscan2
- N4BP2L1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100583010; called by muse, mutect2, varscan2
- NALCN | c.4658T>C p.L1553P | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99213307; called by muse, mutect2, varscan2
- NAP1L2 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100999184; called by muse, mutect2, varscan2
- NAV2 | c.2134G>T p.A712S (on ENST00000396087 / NM_001244963.2; = p.A689S on NM_145117.5) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100584956, COSV62314552; called by muse, mutect2, varscan2
- NCOA2 | c.2002T>A p.S668T | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.706); catalogued as COSV101475915; called by muse, mutect2, varscan2
- NCOA7 | c.2788G>C p.D930H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57654503, COSV99996582; called by muse, mutect2, varscan2
- NIN | c.776C>G p.T259S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99811950; called by muse, mutect2, varscan2
- NLGN1 | c.2261T>G p.L754R | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100848798, COSV100850237, COSV64330434; called by muse, mutect2, varscan2
- NLRP3 | c.2932G>C p.D978H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV100275358; called by muse, mutect2, varscan2
- NPAS4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100214827; called by muse, mutect2, varscan2
- NRXN1 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101276789, COSV101278897; called by muse, mutect2, varscan2
- NRXN2 | c.2007C>A p.D669E | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99632718; called by muse, mutect2, varscan2
- OBSCN | c.16968G>T p.W5656C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV52806947, COSV99473832, COSV99474054; called by muse, mutect2, varscan2
- OCA2 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100667021; called by muse, mutect2, varscan2
- OGDHL | c.1167+1G>C p.X389_splice | Splice Site (SNP) | VAF 41/84 reads (49%) | catalogued as COSV100934212; called by muse, mutect2, varscan2
- OR2T4 | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV100822405; called by muse, mutect2, varscan2
- OR8D1 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100766544; called by muse, mutect2, varscan2
- ORC2 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV99309419; called by muse, mutect2, varscan2
- PAMR1 | c.1250C>A p.P417H (on ENST00000619888 / NM_001001991.3; = p.P434H on NM_015430.4) | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99552189; called by muse, mutect2, varscan2
- PARP14 | c.2694G>C p.R898S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV101506233; called by muse, mutect2, varscan2
- PBX4 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs771158415, COSV99232022; called by muse, mutect2, varscan2
- PCDH8 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100131268; called by muse, mutect2, varscan2
- PCLO | c.14647A>T p.K4883* | Nonsense Mutation (SNP) | VAF 94/397 reads (24%) | catalogued as COSV100428045; called by muse, mutect2, varscan2
- PCLO | c.12728T>G p.F4243C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100428051; called by muse, mutect2, varscan2
- PCSK2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99358818; called by muse, mutect2, varscan2
- PDE10A | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100604587; called by muse, mutect2, varscan2
- PDE1B | c.929A>T p.N310I | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99672224; called by muse, mutect2, varscan2
- PDLIM7 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1161814980, COSV100730141; called by muse, mutect2, varscan2
- PEAR1 | c.3055T>A p.Y1019N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99440741; called by muse, mutect2, varscan2
- PEX3 | c.828T>G p.F276L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); catalogued as COSV100852097; called by muse, mutect2, varscan2
- PFKP | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101126990; called by muse, mutect2
- PIK3CD | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.062); catalogued as rs1037340766, COSV100740005; called by muse, mutect2, varscan2
- PLCB1 | c.1860G>T p.Q620H | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100569586; called by muse, mutect2, varscan2
- PLPPR5 | c.965G>T p.*322Lext*36 (on ENST00000263177 / NM_001037317.2; = p.*317Lext*36 on NM_001010861.3) | Nonstop Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV54179309; called by muse, mutect2, varscan2
- PLXNA4 | c.5405A>C p.K1802T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322771; called by muse, mutect2, varscan2
- POLR1H | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100198418; called by muse, mutect2, varscan2
- PPP1R1A | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99226289; called by muse, mutect2, varscan2
- PRDM9 | c.192A>T p.I64= | Splice Region (SNP) | VAF 52/130 reads (40%) | catalogued as rs750630766, COSV99689872; called by muse, mutect2, varscan2
- PREX2 | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV55798295, COSV99905410; called by muse, mutect2, varscan2
- PROCA1 | c.441-1G>C p.X147_splice (on ENST00000439862 / NM_001366301.1; = p.X119_splice on NM_152465.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 33/156 reads (21%) | catalogued as COSV99972539, COSV99972765; called by muse, mutect2, varscan2
- PRRG2 | c.153C>A p.N51K | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99882308; called by muse, mutect2, varscan2
- PTCD3 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 75/174 reads (43%) | catalogued as COSV99606074; called by muse, mutect2, varscan2
- PTCH2 | c.2837C>G p.P946R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941942, COSV64711033; called by muse, mutect2
- PTER | c.1039A>C p.T347P | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100126563; called by muse, mutect2, varscan2
- PTK2 | c.1332+2T>C p.X444_splice | Splice Site (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100569500; called by muse, mutect2, varscan2
- PTK7 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100029903; called by muse, mutect2, varscan2
- PZP | c.4160T>G p.V1387G | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54357751, COSV99736528; called by muse, mutect2, varscan2
- RAB36 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs144444349; called by muse, mutect2, varscan2
- RAI2 | c.1462A>T p.M488L | Missense Mutation (SNP) | VAF 37/674 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100518174; called by muse, mutect2
- RAPGEF1 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs765844937, COSV100940313; called by muse, mutect2, varscan2
- RASGRF2 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99428635; called by muse, mutect2, varscan2
- REPS2 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100380872; called by muse, mutect2, varscan2
- RNH1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs543262307, COSV100596675; called by muse, mutect2, varscan2
- RPS6KA2 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV55815808; called by muse, mutect2, varscan2
- RTP5 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.142); catalogued as rs373737665; called by muse, mutect2, varscan2
- RUFY4 | c.1008A>T p.E336D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.38); catalogued as COSV100722952; called by muse, mutect2, varscan2
- RYR2 | c.7573T>G p.L2525V | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100768377; called by muse, mutect2, varscan2
- RYR2 | c.12508A>G p.R4170G | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100768378; called by muse, mutect2, varscan2
- SAGE1 | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 123/329 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100186770; called by muse, mutect2, varscan2
- SALL1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1230058496, COSV51761353; called by muse, mutect2, varscan2
- SAMHD1 | c.1504-2A>T p.X502_splice (on ENST00000262878 / NM_001363729.2; = p.X537_splice on NM_015474.4) | Splice Site (SNP) | VAF 76/211 reads (36%) | catalogued as COSV99455756; called by muse, mutect2, varscan2
- SCAF8 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100913954; called by muse, mutect2, varscan2
- SCN1A | c.2309T>C p.V770A (on ENST00000303395 / NM_001202435.3; = p.V759A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100319501; called by muse, mutect2, varscan2
- SEMA3D | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV99405985; called by muse, mutect2, varscan2
- SEMA3F | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as rs554250122, COSV99137235; called by muse, mutect2, varscan2
- SEMA6D | c.2324A>G p.E775G (on ENST00000316364 / NM_153618.2; = p.E713G on NM_020858.2) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316312, COSV60382373; called by muse, mutect2, varscan2
- SEMG1 | c.1326A>C p.E442D | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.286); catalogued as COSV99725088; called by muse, mutect2, varscan2
- SETD5 | c.4235A>G p.Q1412R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100200236; called by muse, mutect2, varscan2
- SF1 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV99917997; called by muse, varscan2
- SH3KBP1 | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101115700; called by muse, mutect2, varscan2
- SIK3 | c.319G>A p.E107K (on ENST00000445177 / NM_001366686.2; = p.E113K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52609664; called by muse, mutect2, varscan2
- SIKE1 | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99285166; called by muse, mutect2, varscan2
- SIKE1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.422); catalogued as COSV99285169; called by muse, mutect2, varscan2
- SKIL | c.2045C>G p.A682G | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV99378088; called by muse, mutect2, varscan2
- SLC10A2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV99807681; called by muse, mutect2, varscan2
- SLC17A4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs369261331, COSV100930657; called by muse, mutect2, varscan2
- SLC22A3 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs373997883, COSV51715505; called by muse, mutect2, varscan2
- SLC24A4 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs776707919, COSV100104381; called by muse, mutect2
- SLC26A4 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 113/237 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99706620; called by muse, mutect2, varscan2
- SLC34A1 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100183800; called by muse, mutect2, varscan2
- SLC38A9 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100591266; called by muse, mutect2, varscan2
- SLC4A4 | c.1450G>A p.A484T (on ENST00000264485 / NM_001098484.3; = p.A440T on NM_003759.4) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99139058; called by muse, mutect2, varscan2
- SLC5A7 | c.1225A>C p.S409R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99886274, COSV99886284; called by muse, mutect2, varscan2
- SLC7A3 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99979370; called by muse, mutect2, varscan2
- SLC8A1 | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100244810; called by muse, mutect2, varscan2
- SLC8A3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.18); catalogued as rs541631348, COSV63522762; called by muse, mutect2, varscan2
- SMARCA4 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 96/157 reads (61%) | catalogued as COSV60786839; called by muse, mutect2, varscan2
- SNTB1 | c.1544G>T p.C515F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101179811; called by muse, mutect2, varscan2
- SNX17 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99277313; called by muse, mutect2, varscan2
- SORCS2 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100211678; called by muse, mutect2, varscan2
- SOX3 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100983664; called by muse, mutect2, varscan2
- SPAG17 | c.5642G>A p.R1881H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs781066299, COSV60459641; called by muse, mutect2, varscan2
- SRRM1 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100104165; called by muse, mutect2, varscan2
- STAM | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 85/170 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101092190; called by muse, mutect2, varscan2
- SVEP1 | c.4047T>G p.C1349W | Missense Mutation (SNP) | VAF 103/434 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237368; called by muse, mutect2, varscan2
- SYCP2 | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1345023700, COSV100698024; called by muse, mutect2, varscan2
- SYNJ2 | c.1128-2A>C p.X376_splice | Splice Site (SNP) | VAF 76/155 reads (49%) | catalogued as COSV100840044, COSV62897462; called by muse, mutect2, varscan2
- TAB2 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV99644566; called by muse, mutect2
- TBC1D7 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 61/260 reads (23%) | catalogued as COSV100568548; called by muse, mutect2, varscan2
- TBX22 | c.798+2T>A p.X266_splice | Splice Site (SNP) | VAF 20/121 reads (17%) | catalogued as COSV100960644; called by muse, mutect2, varscan2
- TCEAL6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.52); catalogued as COSV101035916; called by muse, mutect2
- TCN2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1295178933, COSV99308414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM2 | c.1916A>T p.Q639L (on ENST00000518659 / NM_001122679.2; = p.Q407L on NM_001080428.3) | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101318019, COSV69139280; called by muse, mutect2, varscan2
- TESMIN | c.1478C>A p.S493* | Nonsense Mutation (SNP) | VAF 53/210 reads (25%) | catalogued as COSV54831373, COSV99663398; called by muse, mutect2, varscan2
- THSD7B | c.2506T>A p.S836T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV99745461; called by muse, mutect2, varscan2
- TM9SF2 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899665; called by muse, mutect2, varscan2
- TNXB | c.10208C>A p.P3403H (on ENST00000647633; = p.P3156H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100925965; called by muse, mutect2, varscan2
- TPH2 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 304/478 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV61591380, COSV61593449; called by muse, mutect2, varscan2
- TPP1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV100196821; called by muse, mutect2, varscan2
- TPTE2 | c.865C>G p.H289D (on ENST00000400230 / NM_199254.2; = p.H212D on NM_130785.3) | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55023880, COSV99689779; called by muse, mutect2, varscan2
- TRIP11 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV99970385; called by muse, mutect2, varscan2
- TRMT2A | c.1876T>G p.*626Eext*54 | Nonstop Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99349818; called by muse, varscan2
- TRPM3 | c.787G>C p.E263Q (on ENST00000357533 / NM_001366142.2; = p.E108Q on NM_020952.6) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV100624163; called by muse, mutect2, varscan2
- TRPV5 | c.1788+2T>C p.X596_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99520152; called by muse, mutect2, varscan2
- TRRAP | c.7523C>G p.P2508R (on ENST00000359863 / NM_001244580.1; = p.P2490R on NM_003496.3) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV100722079; called by muse, mutect2, varscan2
- TSPYL1 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100889565; called by muse, mutect2, varscan2
- TTLL8 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.118); catalogued as rs924502633, COSV99838061; called by muse, mutect2
- TTN | c.57796A>C p.K19266Q (on ENST00000591111; = p.K11842Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen possibly damaging (0.724); catalogued as COSV100597329; called by muse, mutect2, varscan2
- TTN | c.55413G>A p.W18471* (on ENST00000591111; = p.W11047* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/616 reads (3%) | catalogued as COSV100597331; called by muse, mutect2
- TTN | c.36128A>G p.K12043R (on ENST00000591111; = p.K4619R on NM_003319.4) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | PolyPhen benign (0.043); catalogued as COSV100597333; called by muse, mutect2, varscan2
- TTN | c.31016A>G p.K10339R (on ENST00000591111; = p.K9412R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | PolyPhen benign (0); catalogued as COSV100597339; called by muse, mutect2, varscan2
- TTN | c.12497A>G p.E4166G (on ENST00000591111; = p.E4120G on NM_003319.4) | Missense Mutation (SNP) | VAF 130/266 reads (49%) | catalogued as COSV100597341; called by muse, mutect2, varscan2
- UBASH3B | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.071); catalogued as COSV99416953, COSV99419159; called by muse, mutect2, varscan2
- UBE3C | c.289T>A p.L97M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs768839052, COSV100779818; called by muse, mutect2, varscan2
- UBXN10 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100907743; called by muse, mutect2, varscan2
- UFL1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs532074525, COSV100990012, COSV65149306; called by muse, mutect2, varscan2
- UGT2B28 | c.1183T>A p.L395M | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.664); catalogued as COSV100158593; called by muse, mutect2, varscan2
- UNC5D | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 128/254 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54776950, COSV99772679; called by muse, mutect2, varscan2
- USH2A | c.897A>T p.Q299H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100230040, COSV100238239; called by muse, mutect2, varscan2
- VAV3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV100579225, COSV100580445; called by muse, mutect2, varscan2
- VCPIP1 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100125375; called by muse, mutect2, varscan2
- VPS13A | c.8812G>C p.D2938H | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652265; called by muse, mutect2, varscan2
- VPS13A | c.8813A>T p.D2938V | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652267; called by muse, mutect2, varscan2
- VSTM4 | c.828A>T p.K276N | Missense Mutation (SNP) | VAF 85/313 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV100251342, COSV100252283; called by muse, mutect2, varscan2
- VWA5A | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100827734, COSV64412002; called by muse, mutect2, varscan2
- VWF | c.3780G>T p.E1260D | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV99778195; called by muse, mutect2, varscan2
- WDR72 | c.2150A>C p.K717T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.224); catalogued as COSV100854274; called by muse, mutect2, varscan2
- WRN | c.3592G>T p.V1198L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV99988393; called by muse, mutect2, varscan2
- ZACN | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100134899; called by muse, mutect2, varscan2
- ZFHX4 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV50818150, COSV99257441; called by muse, mutect2, varscan2
- ZFYVE26 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100720127; called by muse, mutect2, varscan2
- ZNF333 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV99468851; called by muse, mutect2, varscan2
- ZNF362 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100986986; called by muse, mutect2, varscan2
- ZNF608 | c.2166C>A p.N722K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV100101100; called by muse, mutect2, varscan2
- ZNF75D | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100883588; called by muse, mutect2, varscan2
- ZNF76 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99987521; called by muse, mutect2
- ARCN1 | c.978dup p.L327Afs*9 | Frame Shift Ins (INS) | VAF 48/104 reads (46%) | called by mutect2, pindel, varscan2
- CST1 | c.299del p.N100Tfs*35 | Frame Shift Del (DEL) | VAF 48/316 reads (15%) | called by mutect2, varscan2
- ICOS | c.357dup p.K120* | Frame Shift Ins (INS) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- KATNA1 | c.888+1_888+3del p.X296_splice | Splice Site (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- KMT2A | c.3648del p.E1217Rfs*18 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | called by mutect2, pindel, varscan2
- MCC | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- TRAV30 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZNF81 | c.1940del p.F647Sfs*22 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- ADCY9 | c.3678A>G p.R1226= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as COSV99569469; called by muse, mutect2, varscan2
- ANGPT1 | c.660A>G p.Q220= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV52439307; called by muse, mutect2, varscan2
- ANO5 | c.111C>G p.T37= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as COSV100201469; called by muse, mutect2, varscan2
- ATP7A | c.2937C>T p.S979= | Silent (SNP) | VAF 85/494 reads (17%) | catalogued as COSV100430323; called by muse, mutect2, varscan2
- BTN1A1 | c.894T>A p.A298= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV99764219; called by muse, mutect2, varscan2
- CACNA1E | c.6150T>A p.R2050= (on ENST00000367573 / NM_001205293.3; = p.R2007= on NM_000721.4) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100701368; called by muse, mutect2, varscan2
- CAD | c.882C>T p.N294= | Silent (SNP) | VAF 64/338 reads (19%) | catalogued as COSV99254505; called by muse, mutect2, varscan2
- CCNA1 | c.159A>C p.G53= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV99714375; called by muse, mutect2, varscan2
- CCR9 | c.579C>T p.S193= (on ENST00000357632 / NM_031200.3; = p.S181= on NM_006641.4) | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as rs367903658, COSV100591604; called by muse, mutect2, varscan2
- CCT5 | c.27C>T p.F9= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs377019090; called by muse, mutect2, varscan2
- CD200 | c.183C>G p.T61= (on ENST00000473539 / NM_001004196.3; = p.T36= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs757849072, COSV100238167; called by muse, mutect2, varscan2
- COL9A1 | c.2514A>T p.G838= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100294165; called by muse, mutect2, varscan2
- CSF2RB | c.372C>T p.T124= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs141354922; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSRNP3 | c.864G>A p.L288= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100085214, COSV58783777; called by muse, mutect2, varscan2
- CST8 | c.204G>T p.V68= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV99849889; called by muse, mutect2, varscan2
- DAPP1 | c.204G>C p.G68= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99596634; called by muse, mutect2, varscan2
- DCHS1 | c.3093T>C p.P1031= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs957135299, COSV100201583; called by muse, mutect2, varscan2
- DGKE | c.54G>A p.A18= | Silent (SNP) | VAF 70/261 reads (27%) | catalogued as COSV99400707; called by muse, mutect2, varscan2
- DMD | c.5221T>C p.L1741= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as rs1228749524, COSV63747107, COSV63789783; called by muse, mutect2, varscan2
- DNAH7 | c.2625T>A p.S875= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs1019103125, COSV100414093, COSV56786556; called by muse, mutect2, varscan2
- DNMT3B | c.1980C>T p.A660= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as COSV99140518; called by muse, mutect2, varscan2
- DPYD | c.2292A>T p.G764= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV100928753; called by muse, mutect2, varscan2
- DYSF | c.5748C>T p.F1916= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99244008; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.381C>G p.P127= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs888373340, COSV101236908; called by muse, mutect2, varscan2
- EPG5 | c.6918G>A p.L2306= | Silent (SNP) | VAF 53/82 reads (65%) | catalogued as COSV56356394; called by muse, mutect2, varscan2
- F9 | c.558T>G p.T186= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV54380351, COSV54382823, COSV99496388; called by muse, mutect2, varscan2
- FAM47A | c.2292T>G p.T764= | Silent (SNP) | VAF 89/245 reads (36%) | catalogued as COSV100649725, COSV60493933; called by muse, mutect2, varscan2
- FAM71D | c.1020T>A p.T340= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs764115096, COSV100315119; called by muse, mutect2, varscan2
- GALNT3 | c.1449A>G p.K483= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV101204885; called by muse, mutect2
- GLA | c.501A>G p.L167= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as COSV99516202; called by muse, mutect2
- GLI2 | c.2235G>A p.P745= (on ENST00000361492 / NM_001374353.1; = p.P762= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs191591728, COSV58051672; called by muse, mutect2, varscan2
- GLI3 | c.3648C>T p.L1216= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs199638498; called by muse, mutect2, varscan2
- HUWE1 | c.12858T>G p.R4286= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99470839; called by muse, mutect2, varscan2
- ITGBL1 | c.852T>C p.S284= | Silent (SNP) | VAF 56/265 reads (21%) | catalogued as COSV101095112; called by muse, mutect2, varscan2
- JKAMP | c.279C>T p.Y93= (on ENST00000554271 / NM_001284201.1; = p.Y79= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 75/218 reads (34%) | catalogued as rs1183381818, COSV99711403; called by muse, mutect2, varscan2
- KCNG2 | c.1200G>A p.P400= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as rs764200959, COSV60269882; called by muse, mutect2, varscan2
- KCNQ3 | c.2034C>T p.S678= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs560675018, COSV66484537; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA0513 | c.705G>A p.S235= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs148794095; called by muse, mutect2, varscan2
- KRIT1 | c.870T>C p.F290= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100388623; called by muse, mutect2, varscan2
- LHX1 | c.1146G>A p.L382= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.621A>C p.R207= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV101277696; called by muse, mutect2, varscan2
- MAJIN | c.300T>A p.V100= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV100104183; called by muse, mutect2, varscan2
- MAP2 | c.1308T>C p.T436= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99558228; called by muse, mutect2, varscan2
- MAP2 | c.4830T>G p.S1610= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV52284688, COSV52309260, COSV99561686; called by muse, mutect2, varscan2
- MED13L | c.2733A>G p.T911= | Silent (SNP) | VAF 88/244 reads (36%) | catalogued as COSV99927997; called by muse, mutect2, varscan2
- MSR1 | c.471G>T p.L157= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs1412047974, COSV100026693, COSV50544582; called by muse, varscan2
- MTMR2 | c.1689C>A p.V563= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV100334597; called by muse, mutect2, varscan2
- NAV1 | c.4668C>A p.L1556= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99818302; called by muse, mutect2, varscan2
- NCKAP5 | c.5286T>G p.S1762= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV100490350; called by muse, mutect2, varscan2
- NMUR1 | c.153C>T p.Y51= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs200356713, COSV100531821; called by muse, mutect2, varscan2
- NRG1 | c.222G>A p.G74= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs1400233918, COSV99827807; called by muse, mutect2, varscan2
- NRXN3 | c.1809C>T p.I603= (on ENST00000557594 / NM_001272020.2; = p.I1027= on NM_004796.6) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99816406; called by muse, mutect2, varscan2
- OPRM1 | c.1039C>A p.R347= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs200512398, COSV100000556; called by muse, mutect2, varscan2
- OR10AG1 | c.201C>T p.I67= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV100399989, COSV56634499; called by muse, mutect2, varscan2
- OR10K1 | c.609T>C p.G203= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as COSV99193272; called by muse, mutect2, varscan2
- OR13C4 | c.57T>G p.G19= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV52926306, COSV99470003; called by muse, mutect2, varscan2
- OR2G3 | c.483T>C p.T161= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs145229745; called by muse, mutect2, varscan2
- OR4C46 | c.786T>G p.T262= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as COSV100060447; called by muse, mutect2, varscan2
- OR5T2 | c.669C>T p.L223= | Silent (SNP) | VAF 82/198 reads (41%) | catalogued as COSV100506831; called by muse, mutect2, varscan2
- PADI3 | c.1893T>A p.I631= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100968409; called by muse, mutect2, varscan2
- PCDH1 | c.2244C>A p.V748= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV99745599; called by muse, mutect2, varscan2
- PCLO | c.11739T>C p.T3913= | Silent (SNP) | VAF 126/494 reads (26%) | catalogued as COSV100428055, COSV61624717; called by muse, mutect2, varscan2
- PLXNA3 | c.5484C>T p.N1828= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs1377284419, COSV100859827; called by muse, mutect2, varscan2
- PSMD8 | c.966G>A p.Q322= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as COSV53058164; called by muse, mutect2, varscan2
- RAI2 | c.1461C>A p.S487= | Silent (SNP) | VAF 37/674 reads (5%) | catalogued as COSV100518175; called by muse, mutect2
- RARB | c.507T>G p.T169= (on ENST00000383772 / NM_001290216.2; = p.T162= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100412166; called by muse, mutect2, varscan2
- RGL4 | c.1341C>G p.V447= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99318647; called by muse, mutect2, varscan2
- RPS6KA6 | c.1545C>T p.F515= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV99424191; called by muse, mutect2, varscan2
- RRBP1 | c.2995C>T p.L999= (on ENST00000377813 / NM_001365613.2; = p.L566= on NM_004587.3) | Silent (SNP) | VAF 32/290 reads (11%) | catalogued as COSV99853642; called by muse, mutect2
- RUNDC3B | c.177T>G p.S59= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV99712295; called by muse, mutect2, varscan2
- SALL4 | c.2139C>T p.P713= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99409242; called by muse, mutect2, varscan2
- SCN1A | c.5016C>T p.N1672= (on ENST00000303395 / NM_001202435.3; = p.N1661= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as rs778952115, COSV100319500, COSV57668569; called by muse, mutect2, varscan2
- SEMA3D | c.144C>A p.T48= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV52395218; called by muse, mutect2, varscan2
- SGSM1 | c.3408C>T p.D1136= (on ENST00000400359 / NM_001039948.4; = p.D1075= on NM_133454.3) | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV101240469; called by muse, mutect2, varscan2
- SIPA1L1 | c.1176G>A p.L392= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs772922028, COSV100665195; called by muse, mutect2, varscan2
- SKIV2L | c.2605A>C p.R869= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as COSV100514571; called by muse, mutect2, varscan2
- SLC14A2 | c.2628C>A p.T876= | Silent (SNP) | VAF 100/303 reads (33%) | catalogued as rs556254338, COSV54907211, COSV99675126; called by muse, mutect2, varscan2
- SLC17A9 | c.1281G>C p.V427= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as COSV64846852; called by muse, mutect2, varscan2
- SYNDIG1L | c.510C>G p.L170= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1403138110, COSV100526408; called by muse, mutect2, varscan2
- SYNE2 | c.4803A>G p.L1601= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100646865; called by muse, mutect2, varscan2
- TAF1 | c.3858A>T p.T1286= (on ENST00000373790 / NM_138923.4; = p.T1307= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/247 reads (19%) | catalogued as COSV99334697; called by muse, mutect2, varscan2
- TRHDE | c.1854T>C p.H618= | Silent (SNP) | VAF 95/178 reads (53%) | catalogued as COSV99669377; called by muse, mutect2, varscan2
- TRIP12 | c.5637G>A p.L1879= | Silent (SNP) | VAF 91/214 reads (43%) | catalogued as COSV52266975, COSV99389494; called by muse, mutect2, varscan2
- WDR44 | c.195A>G p.E65= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs746792525, COSV99561233; called by muse, mutect2, varscan2
- ZNF197 | c.465A>T p.V155= | Silent (SNP) | VAF 48/74 reads (65%) | catalogued as COSV100482008; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610609 C>T | 5'Flank (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99677593; called by muse, mutect2, varscan2
- DEFB119 | c.61+1383T>A | Intron (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100190585; called by muse, mutect2, varscan2
- DZANK1 | c.543+722G>A | Intron (SNP) | VAF 42/123 reads (34%) | catalogued as COSV99361926; called by muse, mutect2, varscan2
- GABRE | c.784+1190A>C | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as rs1323267730, COSV100944225; called by muse, mutect2, varscan2
- KIF16B | c.3498+2786G>A | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100733856; called by muse, mutect2, varscan2
- PCDH11X | c.3033+3646A>T | Intron (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100008893; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1279+26G>T | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99460914; called by muse, mutect2, varscan2
- SLC17A2 | c.*55C>G | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99613956; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48014A>C | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as COSV67442844; called by muse, mutect2, varscan2
- TBX1 | chr22:19782968 G>T | 3'Flank (SNP) | VAF 112/209 reads (54%) | catalogued as COSV100283959; called by muse, mutect2, varscan2
- TTN | c.10361-4669A>G | Intron (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100597344; called by muse, mutect2, varscan2
